Somatic mutation profile of tumor specimen TCGA-YS-A95C-01A (aliquot TCGA-YS-A95C-01A-11D-A39R-32) from TCGA case TCGA-YS-A95C, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 54.3 years (19,818 days).
Specimen TCGA-YS-A95C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fcc92840-37df-40e3-a43c-b91d5fb8b368.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YS-A95C-10B (Blood Derived Normal), aliquot TCGA-YS-A95C-10B-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3246feb-e00a-41c5-a94d-42f4c0ac2098

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.13T>G p.W5G | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56238190; called by muse, mutect2, varscan2
- ITGB6 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755036686; called by muse, mutect2, varscan2
- ITGBL1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs149770736; called by muse, mutect2, varscan2
- OFD1 | c.230T>C p.L77S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1555900746; ClinVar: uncertain significance; called by muse, varscan2
- PNP | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs568276040; called by muse, mutect2, varscan2
- SERPINE2 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs368896299, COSV51458995; called by muse, mutect2, varscan2
- BAP1 | c.630_632del p.I210del | In Frame Del (DEL) | VAF 10/52 reads (19%) | called by pindel, varscan2
- CPXM1 | c.2078C>T p.P693L | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FAM78B | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- NSD1 | c.7341G>C p.Q2447H | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- PHB | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- PRKDC | c.8170G>A p.D2724N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PROSER1 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC25A24 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- STKLD1 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VNN3 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADGRB3 | c.72T>G p.A24= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as COSV101002005; called by muse, mutect2, varscan2
- ADRB3 | c.72C>A p.T24= | Silent (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- OR6B3 | c.282C>T p.F94= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs751578693, COSV60113642; called by mutect2, varscan2
- SETD1A | c.2895G>A p.G965= | Silent (SNP) | VAF 35/138 reads (25%) | called by muse, mutect2, varscan2
- SMCO1 | c.72G>A p.A24= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs371593591, COSV66877345; called by muse, mutect2, varscan2
- PANK3 | c.936+431G>T | Intron (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
